Somatic mutation profile of tumor specimen HTMCP-03-06-02061-01A (aliquot HTMCP-03-06-02061-01A-01D-4427) from CGCI case HTMCP-03-06-02061, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2.
Specimen HTMCP-03-06-02061-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f114d66-8e5f-49f3-8b71-f6fd18b1588a.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02061-10A (Blood Derived Normal), aliquot HTMCP-03-06-02061-10A-01D-4427; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/caa5b59e-bb1b-4462-9449-65a67b7809b2

The open-access MAF lists 157 somatic variants for this specimen: 109 protein-altering or splice-affecting, 39 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 39, Nonsense Mutation 12, 3'UTR 3, RNA 3, Intron 2, Splice Site 2, Frame Shift Del 1, Splice Region 1, 3'Flank 1, Nonstop Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 13/28 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 30/111 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 13/78 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ZFYVE26 | c.1477C>T p.Q493* | Nonsense Mutation (SNP) | VAF 11/74 reads (15%) | catalogued as rs118204050, CM081475, COSV61325266; ClinVar: pathogenic; called by muse, varscan2
- ABCB4 | c.2620G>A p.E874K | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV99710725; called by muse, mutect2, varscan2
- ANK2 | c.10816C>T p.P3606S | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100003895, COSV52194991; called by muse, mutect2, varscan2
- ANO7 | c.223G>A p.E75K (on ENST00000274979; = p.E21K on NM_001001666.4) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.034); catalogued as COSV99238012; called by muse, mutect2, varscan2
- ARHGEF6 | c.1365A>C p.Q455H | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.376); catalogued as COSV99166841; called by muse, mutect2, varscan2
- ASTN2 | c.1940C>T p.S647F (on ENST00000313400 / NM_001365069.1; = p.S596F on NM_014010.5) | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV57767227, COSV57817020; called by muse, mutect2, varscan2
- ATP8A2 | c.1238C>G p.S413* | Nonsense Mutation (SNP) | VAF 34/127 reads (27%) | catalogued as COSV54934047; called by muse, mutect2, varscan2
- ATRX | c.5653C>T p.H1885Y | Missense Mutation (SNP) | VAF 66/257 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64875950; called by muse, mutect2, varscan2
- BRWD3 | c.892C>T p.H298Y | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV64745652; called by muse, mutect2, varscan2
- CD163L1 | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT tolerated (0.93); PolyPhen benign (0.006); catalogued as rs762956882, COSV58013579; called by muse, mutect2, varscan2
- DCC | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV59085913; called by muse, mutect2, varscan2
- DENND2B | c.2197C>T p.R733* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as COSV58203858; called by muse, mutect2, varscan2
- DLC1 | c.3881G>A p.R1294H (on ENST00000276297 / NM_001348081.2; = p.R857H on NM_006094.5) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.097); catalogued as rs369441118; called by muse, mutect2, varscan2
- EVPL | c.3355C>T p.R1119C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs770411485, COSV56916558; called by muse, mutect2, varscan2
- FAM120A | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 47/168 reads (28%) | catalogued as COSV99465605; called by muse, mutect2, varscan2
- FBXW7 | c.1408C>G p.H470D (on ENST00000281708 / NM_001349798.2; = p.H390D on NM_018315.5) | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.449); catalogued as COSV55911610; called by muse, mutect2, varscan2
- FN1 | c.2979G>C p.Q993H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.862); catalogued as COSV60558388; called by muse, mutect2, varscan2
- FOXL2 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.116); catalogued as COSV57726683, COSV57731709; called by muse, mutect2, varscan2
- GAS6 | c.1631C>A p.S544Y | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs758520989; called by muse, mutect2, varscan2
- HGS | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs954145545; called by muse, mutect2, varscan2
- JAKMIP1 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746008481, COSV51530389; called by muse, mutect2, varscan2
- JMJD1C | c.2695-1G>C p.X899_splice | Splice Site (SNP) | VAF 15/56 reads (27%) | catalogued as COSV100550865; called by muse, mutect2, varscan2
- KHDRBS3 | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs373981616; called by muse, mutect2, varscan2
- KNDC1 | c.228G>C p.Q76H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs1234768986; called by muse, mutect2, varscan2
- LDB3 | c.1618G>C p.E540Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as COSV53946275; called by muse, mutect2, varscan2
- LRP1B | c.2545G>C p.E849Q | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV63342053; called by muse, mutect2, varscan2
- MAST1 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.119); catalogued as COSV52243225; called by muse, mutect2
- MGA | c.2137G>A p.D713N | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV54961793; called by muse, mutect2, varscan2
- NUP93 | c.2221-1G>A p.X741_splice | Splice Site (SNP) | VAF 16/73 reads (22%) | catalogued as COSV57428522; called by muse, mutect2, varscan2
- OR2M5 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.197); catalogued as COSV63545710; called by muse, mutect2, varscan2
- PDPR | c.1535C>T p.S512F | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV99848758; called by muse, mutect2
- RAD54L2 | c.4271C>G p.A1424G | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV56578090; called by muse, mutect2, varscan2
- RGPD8 | c.5288C>T p.S1763F | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); catalogued as COSV56898744; called by muse, mutect2, varscan2
- RUNX1T1 | c.1519C>T p.Q507* (on ENST00000265814 / NM_001198628.1; = p.Q480* on NM_004349.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/48 reads (38%) | catalogued as COSV56157453; called by muse, mutect2, varscan2
- RYR1 | c.6670C>T p.R2224C | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as rs199870223; ClinVar: uncertain significance; called by mutect2, varscan2
- SERPINI1 | c.1177C>G p.R393G | Missense Mutation (SNP) | VAF 99/294 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761133163, CM138046, COSV55508793; called by muse, mutect2, varscan2
- SIN3B | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1370973429; called by muse, mutect2
- SIPA1L1 | c.1168G>C p.E390Q | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62168445; called by muse, mutect2, varscan2
- SLIT2 | c.4069G>A p.E1357K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.075); catalogued as rs1276493567, COSV99882954; called by muse, mutect2, varscan2
- SOS2 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 97/237 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as rs375244948; called by muse, mutect2, varscan2
- SPINK5 | c.3048C>G p.D1016E | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.79); catalogued as COSV56252451; called by muse, mutect2, varscan2
- TAF6L | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.535); catalogued as COSV53668256; called by muse, mutect2, varscan2
- TENM1 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV64427970; called by muse, mutect2, varscan2
- TGFBR3 | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV53022438; called by muse, mutect2, varscan2
- TP63 | c.1046G>C p.G349A | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as CM083196, COSV53197460, COSV53207297, COSV53220659; called by muse, mutect2, varscan2
- TRAPPC9 | c.1657C>T p.R553W | Missense Mutation (SNP) | VAF 72/218 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs769467379, COSV66894126; called by muse, varscan2
- TRPC3 | c.2408G>A p.R803K (on ENST00000379645 / NM_001366479.2; = p.R730K on NM_003305.2) | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53376361; called by muse, mutect2, varscan2
- TRPV4 | c.956C>T p.S319L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as rs377518118; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.14842G>A p.E4948K (on ENST00000591111; = p.E4021K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | PolyPhen benign (0.029); catalogued as rs1370636944; called by muse, mutect2, varscan2
- UNC13A | c.1856G>A p.R619Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.434); catalogued as COSV53203075; called by muse, mutect2, varscan2
- ABCA13 | c.14375C>A p.S4792Y | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- ACAP2 | c.1889C>T p.A630V | Missense Mutation (SNP) | VAF 70/442 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ACSS2 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- AHCTF1 | c.6262G>T p.E2088* (on ENST00000366508; = p.E2062* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 49/156 reads (31%) | called by muse, mutect2, varscan2
- AHCTF1 | c.5537G>A p.R1846K (on ENST00000366508; = p.R1820K on NM_015446.5) | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- AKAP13 | c.3941C>T p.T1314I | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANO8 | c.3292G>A p.E1098K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ARHGEF6 | c.1733G>A p.G578E | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATP7A | c.3675G>C p.L1225F | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATRX | c.3197A>G p.K1066R | Missense Mutation (SNP) | VAF 56/296 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BAZ1A | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.054); called by mutect2, varscan2
- BRD4 | c.4088G>C p.*1363Sext*7 | Nonstop Mutation (SNP) | VAF 5/31 reads (16%) | called by muse, varscan2
- BRD4 | c.3790G>A p.E1264K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CCDC141 | c.4211_4213delinsAA p.L1404Qfs*15 | Frame Shift Del (DEL) | VAF 16/133 reads (12%) | called by pindel, varscan2*
- CCDC87 | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CEP192 | c.3571G>A p.E1191K | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHD9 | c.2113-5C>G | Splice Region (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- CIC | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); called by muse, mutect2
- CLK1 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 87/254 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- COL25A1 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, varscan2
- CT47B1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- DIS3L | c.2771G>T p.G924V (on ENST00000319212 / NM_001143688.3; = p.G841V on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- FAM186A | c.3179G>C p.G1060A | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- FSIP2 | c.20387C>T p.S6796L | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- HEPH | c.2440dup p.I814Nfs*4 (on ENST00000343002; = p.I547Nfs*4 on NM_014799.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 28/89 reads (31%) | called by mutect2, pindel, varscan2
- KALRN | c.7357G>C p.D2453H (on ENST00000360013 / NM_001024660.4; = p.D756H on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/221 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA1210 | c.4328C>T p.S1443F | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- LAMA1 | c.2605G>C p.E869Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- LATS1 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- LRCH2 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- LRCH2 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- MADCAM1 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- MARF1 | c.1913C>T p.S638F | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- MUC16 | c.7831A>T p.I2611F | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- MUC17 | c.6883G>C p.E2295Q | Missense Mutation (SNP) | VAF 124/478 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MYH10 | c.4984G>A p.E1662K | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- MYO1C | c.265C>T p.P89S (on ENST00000648651 / NM_001080779.2; = p.P54S on NM_033375.5) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NUP93 | c.2098G>C p.D700H | Missense Mutation (SNP) | VAF 46/256 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- PCDH10 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- PCDH11X | c.2507G>T p.C836F | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKHD1L1 | c.2593C>T p.Q865* | Nonsense Mutation (SNP) | VAF 20/111 reads (18%) | called by muse, mutect2, varscan2
- PRUNE2 | c.2977G>T p.E993* | Nonsense Mutation (SNP) | VAF 47/159 reads (30%) | called by muse, mutect2, varscan2
- PZP | c.1663G>C p.E555Q | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- RNF180 | c.1570C>G p.L524V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.94); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SEC23A | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- SLIT2 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- SPECC1L | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- SVIL | c.2746G>C p.E916Q (on ENST00000355867 / NM_021738.3; = p.E490Q on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- SYNE2 | c.7165T>G p.S2389A | Missense Mutation (SNP) | VAF 63/96 reads (66%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2
- TENM3 | c.3313G>A p.E1105K | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- THOC2 | c.1984C>T p.Q662* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- TMEM132D | c.2170G>T p.D724Y | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBQLN1 | c.337C>G p.Q113E | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- VWA5B1 | c.3002C>T p.S1001F (on ENST00000375079; = p.S996F on NM_001039500.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- ZNF207 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 58/183 reads (32%) | called by muse, mutect2, varscan2
- ZNF730 | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- ABCA13 | c.12774C>G p.L4258= | Silent (SNP) | VAF 20/75 reads (27%) | called by muse, mutect2, varscan2
- ADGRG6 | c.2922C>T p.F974= | Silent (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- ANO2 | c.2757C>T p.L919= (on ENST00000356134 / NM_001278597.3; = p.L923= on NM_001278596.3) | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs185209166; called by muse, mutect2, varscan2
- APC | c.1707G>C p.V569= | Silent (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2, varscan2
- ASTN1 | c.3084C>T p.L1028= | Silent (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- CDH7 | c.750G>A p.V250= | Silent (SNP) | VAF 39/120 reads (33%) | catalogued as rs1436021242; called by muse, mutect2, varscan2
- CEP192 | c.3984C>G p.L1328= | Silent (SNP) | VAF 37/126 reads (29%) | called by muse, mutect2, varscan2
- CHD3 | c.3564G>A p.A1188= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs773170300, COSV57872311; called by muse, mutect2, varscan2
- CNOT1 | c.6865C>T p.L2289= | Silent (SNP) | VAF 40/153 reads (26%) | catalogued as COSV54700171; called by muse, mutect2, varscan2
- CTNNA2 | c.1206C>T p.L402= | Silent (SNP) | VAF 35/110 reads (32%) | called by muse, mutect2, varscan2
- CUL4B | c.804C>T p.I268= | Silent (SNP) | VAF 25/108 reads (23%) | called by muse, mutect2, varscan2
- DOCK2 | c.5175G>A p.R1725= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV56987251; called by muse, mutect2, varscan2
- ENTR1 | c.492C>T p.F164= (on ENST00000357365 / NM_001039707.2; = p.F141= on NM_006643.4) | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs533889709; called by muse, mutect2, varscan2
- ERAP1 | c.2846G>A p.*949= | Silent (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- FLNA | c.4344G>A p.A1448= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs782529594, CD149441, COSV100775039; ClinVar: likely benign; called by muse, varscan2
- HGF | c.339C>T p.G113= | Silent (SNP) | VAF 19/69 reads (28%) | called by muse, mutect2, varscan2
- IL2RG | c.396C>G p.L132= | Silent (SNP) | VAF 17/101 reads (17%) | called by muse, mutect2, varscan2
- IRS4 | c.1992G>A p.T664= | Silent (SNP) | VAF 41/212 reads (19%) | catalogued as rs765352679, COSV64532622; called by muse, mutect2, varscan2
- ITIH6 | c.1176C>T p.I392= | Silent (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- KCNAB1 | c.184C>T p.L62= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as rs1217400530; called by muse, mutect2, varscan2
- KIF15 | c.396G>A p.L132= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV58160270; called by muse, mutect2, varscan2
- KIF26B | c.5235G>A p.A1745= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs747644735, COSV100833223; called by muse, mutect2, varscan2
- LIMA1 | c.1335C>G p.L445= | Silent (SNP) | VAF 36/137 reads (26%) | catalogued as rs1047345968, COSV57964786; called by muse, mutect2, varscan2
- LRP1B | c.789G>A p.Q263= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as rs770394521, COSV101257980, COSV67184989; called by muse, mutect2, varscan2
- MAP3K10 | c.396G>A p.E132= | Silent (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- MECOM | c.123C>T p.L41= | Silent (SNP) | VAF 28/142 reads (20%) | catalogued as rs1383091023; called by muse, mutect2, varscan2
- MED13 | c.6348A>G p.K2116= | Silent (SNP) | VAF 25/97 reads (26%) | called by muse, mutect2, varscan2
- MEGF8 | c.1098C>T p.F366= | Silent (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- NRAP | c.1074C>G p.L358= | Silent (SNP) | VAF 27/110 reads (25%) | catalogued as rs775904760, COSV100748391; called by muse, mutect2, varscan2
- NUP93 | c.2310G>A p.S770= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as rs542681313, COSV100360542; called by muse, mutect2, varscan2
- PLEKHG2 | c.1107G>A p.E369= | Silent (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- PRUNE2 | c.5221C>T p.L1741= | Silent (SNP) | VAF 46/110 reads (42%) | catalogued as COSV65045762; called by muse, mutect2, varscan2
- SI | c.2628G>A p.Q876= | Silent (SNP) | VAF 38/233 reads (16%) | catalogued as COSV52264845; called by muse, mutect2, varscan2
- SLCO5A1 | c.2466G>A p.P822= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV99480476; called by muse, mutect2, varscan2
- SYNE1 | c.1608G>A p.V536= (on ENST00000367255 / NM_182961.4; = p.V543= on NM_033071.3) | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as rs267600866; called by muse, mutect2, varscan2
- TNC | c.1743C>T p.H581= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs765892334, COSV60786384, COSV60790591; called by muse, mutect2, varscan2
- TTN | c.32808G>A p.K10936= (on ENST00000591111; = p.K10009= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/110 reads (27%) | catalogued as COSV60172985; called by muse, mutect2, varscan2
- TTN | c.9318G>A p.Q3106= (on ENST00000591111; = p.Q3060= on NM_003319.4) | Silent (SNP) | VAF 30/126 reads (24%) | catalogued as COSV60190831, COSV60260868; called by muse, mutect2, varscan2
- UNC80 | c.3201C>T p.R1067= | Silent (SNP) | VAF 20/91 reads (22%) | called by muse, mutect2, varscan2
- AC133485.7 | n.3163C>G | RNA (SNP) | VAF 64/336 reads (19%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.2006+1374G>C | Intron (SNP) | VAF 21/105 reads (20%) | called by muse, mutect2, varscan2
- CPED1 | c.*8G>T | 3'UTR (SNP) | VAF 29/86 reads (34%) | called by muse, mutect2, varscan2
- FLJ12825 | n.1983G>T | RNA (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2, varscan2
- HSP90AA1 | c.*10G>A | 3'UTR (SNP) | VAF 82/172 reads (48%) | called by muse, mutect2, varscan2
- MAGEB3 | c.*8G>A | 3'UTR (SNP) | VAF 14/60 reads (23%) | catalogued as COSV100854643; called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640895 C>T | 3'Flank (SNP) | VAF 17/70 reads (24%) | catalogued as rs375582710; called by muse, varscan2
- SSPOP | n.7436C>G | RNA (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- TEPSIN | c.49-28C>T | Intron (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
